Somatic mutation profile of tumor specimen TCGA-64-5779-01A (aliquot TCGA-64-5779-01A-01D-1625-08) from TCGA case TCGA-64-5779, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.1 years (22,305 days).
Specimen TCGA-64-5779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 689ebff3-25a3-4492-8391-0bbb7919dcc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-5779-10A (Blood Derived Normal), aliquot TCGA-64-5779-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6d4d79d-d385-4efc-a945-c83d419eb827

The open-access MAF lists 391 somatic variants for this specimen: 306 protein-altering or splice-affecting, 79 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 263, Silent 79, Nonsense Mutation 19, Frame Shift Del 11, Splice Site 5, Intron 4, Frame Shift Ins 3, Splice Region 3, RNA 1, 3'UTR 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.1124T>A p.L375Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221546; called by muse, mutect2, varscan2
- ABCC3 | c.1693G>T p.A565S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53321140; called by muse, mutect2, varscan2
- ABCD2 | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58052268; called by muse, mutect2, varscan2
- ABHD6 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV99917085; called by muse, mutect2
- ACAP3 | c.1016A>T p.K339M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100686599; called by muse, mutect2
- ACOX3 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as COSV62712319; called by muse, mutect2
- ADAMTS3 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54393692; called by muse, mutect2, varscan2
- ADGRB3 | c.3514G>T p.D1172Y | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV53247619, COSV53261891; called by muse, mutect2, varscan2
- ADGRG1 | c.1771A>T p.T591S | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV65635758; called by muse, mutect2, varscan2
- AFAP1L2 | c.1239C>G p.Y413* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV58415515; called by muse, mutect2, varscan2
- AGXT2 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51487223; called by muse, mutect2, varscan2
- AHSG | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56608080; called by muse, mutect2, varscan2
- AIFM2 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as COSV57159480; called by muse, mutect2
- AKAP6 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV55216503; called by muse, mutect2, varscan2
- ALDOB | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66398009; called by muse, mutect2, varscan2
- ALG9 | c.1799G>T p.R600L (on ENST00000614444 / NM_001352418.1; = p.R607L on NM_024740.2) | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV67644500; called by muse, mutect2, varscan2
- ANK1 | c.3763C>A p.R1255S | Missense Mutation (SNP) | VAF 135/514 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as COSV55883728; called by muse, mutect2, varscan2
- ANTXR1 | c.1186-1G>T p.X396_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58014768; called by muse, mutect2
- ANTXR2 | c.1176G>T p.M392I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV56316033; called by muse, mutect2
- AP2A2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1453495639, COSV59961011; called by muse, mutect2, varscan2
- ARAP1 | c.1310G>T p.G437V (on ENST00000393609 / NM_001040118.2; = p.G192V on NM_015242.4) | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs778511032, COSV61991675; called by muse, mutect2, varscan2
- ARAP3 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs781686907, COSV53351218; called by muse, mutect2, varscan2
- ARHGAP1 | c.717C>A p.N239K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV61735128; called by muse, mutect2, varscan2
- ARHGAP31 | c.1981A>G p.K661E | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51794087; called by muse, mutect2, varscan2
- ARHGEF25 | c.1339C>A p.Q447K | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV54087145; called by muse, mutect2, varscan2
- ARHGEF3 | c.1244G>T p.R415I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56327873; called by muse, mutect2, varscan2
- ASCC3 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV61229390; called by muse, mutect2, varscan2
- ASL | c.397T>A p.S133T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV59188538; called by muse, mutect2, varscan2
- ASPRV1 | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100208569; called by muse, mutect2, varscan2
- ASTN1 | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as COSV56064899, COSV56071491; called by muse, mutect2, varscan2
- ASTN2 | c.1527G>T p.W509C (on ENST00000313400 / NM_001365069.1; = p.W458C on NM_014010.5) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57761560; called by muse, mutect2, varscan2
- ASTN2 | c.1526G>T p.W509L (on ENST00000313400 / NM_001365069.1; = p.W458L on NM_014010.5) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV100528976; called by muse, mutect2, varscan2
- ATG2A | c.5771A>G p.H1924R | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as rs911843956, COSV63475623; called by muse, mutect2, varscan2
- ATP1A2 | c.291del p.F98Sfs*72 | Frame Shift Del (DEL) | VAF 58/203 reads (29%) | catalogued as COSV63403422; called by mutect2, pindel, varscan2
- ATXN3L | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 122/203 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV66075808; called by muse, mutect2, varscan2
- AVPR1A | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs865851696, COSV54546941; called by muse, mutect2, varscan2
- AVPR1A | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54546952; called by muse, mutect2, varscan2
- BLM | c.2481G>A p.M827I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV61924685; called by mutect2, varscan2
- BRINP3 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV66526983; called by muse, mutect2, varscan2
- C10orf71 | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as rs1034754853, COSV100110403, COSV60510613; called by muse, mutect2, varscan2
- C8orf74 | c.295del p.R99Gfs*39 | Frame Shift Del (DEL) | VAF 38/125 reads (30%) | catalogued as COSV58754815; called by mutect2, pindel, varscan2
- CAAP1 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV61700903; called by muse, mutect2, varscan2
- CACNA1E | c.5689C>T p.P1897S | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV62399449; called by muse, mutect2, varscan2
- CAPNS2 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.117); catalogued as COSV100045059, COSV50896101; called by muse, mutect2, varscan2
- CARNS1 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs375219127; called by muse, mutect2
- CASS4 | c.1756C>A p.L586I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64386762; called by muse, mutect2, varscan2
- CD163 | c.46+1G>C p.X16_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100775992; called by muse, mutect2, varscan2
- CD177 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV65121513; called by muse, mutect2, varscan2
- CDK15 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.081); catalogued as COSV53635178; called by muse, mutect2, varscan2
- CEP170 | c.2954G>A p.R985K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100316612, COSV100317759, COSV60509960; called by mutect2, varscan2
- CHL1 | c.3507G>T p.E1169D (on ENST00000397491 / NM_001253387.1; = p.E1185D on NM_006614.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as COSV56595396; called by muse, mutect2, varscan2
- CHPF | c.1895C>G p.A632G | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60535058; called by muse, mutect2, varscan2
- CHRM5 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1475008854, COSV67247603; called by muse, mutect2
- CHST12 | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1159328312, COSV51675832; called by muse, mutect2, varscan2
- CHSY3 | c.842G>T p.S281I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100519559, COSV59283618; called by muse, mutect2, varscan2
- CIC | c.3565G>T p.V1189L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV50586820; called by muse, mutect2, varscan2
- CLTC | c.4617G>T p.Q1539H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV52248484; called by muse, mutect2, varscan2
- CLYBL | c.635-1G>T p.X212_splice | Splice Site (SNP) | VAF 26/69 reads (38%) | catalogued as COSV59222743; called by muse, mutect2, varscan2
- CMPK2 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV56775022; called by muse, mutect2, varscan2
- CNKSR1 | c.1658C>G p.P553R (on ENST00000374253 / NM_001297647.2; = p.P546R on NM_006314.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58793485; called by muse, mutect2, varscan2
- CNTNAP5 | c.2795C>A p.S932Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV70489662; called by muse, mutect2, varscan2
- COL10A1 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV54573288; called by muse, mutect2, varscan2
- COL12A1 | c.7004G>A p.G2335E | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59397543; called by muse, mutect2, varscan2
- COL4A1 | c.4732T>A p.W1578R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65427005; called by muse, mutect2, varscan2
- CPN1 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV64942381; called by muse, mutect2
- CPT1C | c.941C>A p.T314K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54918109, COSV54919807; called by muse, mutect2, varscan2
- CR1 | c.3383C>A p.P1128H | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1421409370, COSV100887855; called by muse, mutect2, varscan2
- CSMD1 | c.5696T>A p.V1899E (on ENST00000520002; = p.V1898E on NM_033225.6) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59333920; called by muse, mutect2, varscan2
- CSMD1 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68212760; called by muse, mutect2, varscan2
- DACH2 | c.862G>C p.A288P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV64171484; called by muse, mutect2, varscan2
- DCAF12L2 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.86); PolyPhen benign (0.086); catalogued as COSV100758539, COSV63582082; called by muse, mutect2, varscan2
- DCAF4L2 | c.744del p.F249Lfs*25 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | catalogued as COSV60476942; called by mutect2, pindel, varscan2
- DCC | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as COSV59107348, COSV59134751; called by muse, mutect2, varscan2
- DCTD | c.403A>T p.S135C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV63866965; called by muse, mutect2, varscan2
- DDX58 | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV101153045; called by muse, mutect2, varscan2
- DDX60 | c.1932A>T p.L644F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67097090; called by muse, mutect2, varscan2
- DDX60 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV67097095; called by muse, mutect2, varscan2
- DENND5B | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as rs758268350, COSV60903319; called by muse, mutect2, varscan2
- DGKI | c.1503C>G p.N501K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as COSV55954163; called by muse, mutect2, varscan2
- DHRS7C | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100364573; called by muse, mutect2, varscan2
- DIAPH2 | c.714A>C p.K238N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61272972; called by muse, mutect2
- DIAPH2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61272987; called by muse, mutect2
- DICER1 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV58621624, COSV58628321; called by muse, mutect2, varscan2
- DISP3 | c.4015G>A p.A1339T | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as rs372266249; called by muse, mutect2, varscan2
- DLEC1 | c.2077G>T p.D693Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57295135, COSV57300827; called by muse, mutect2, varscan2
- DLG2 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.671); catalogued as rs1414599025, COSV54646625; called by muse, mutect2, varscan2
- DLGAP2 | c.2314A>T p.S772C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV70099426; called by muse, mutect2, varscan2
- DNAI3 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV54003183; called by muse, mutect2, varscan2
- DPYS | c.1236G>T p.R412S | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100679786, COSV100679807, COSV100679871; called by muse, mutect2
- DPYS | c.1236-1G>T p.X412_splice | Splice Site (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100679872; called by muse, mutect2
- DSCAM | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68641460; called by muse, mutect2, varscan2
- DZIP3 | c.1364C>A p.P455H | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64312385; called by muse, mutect2, varscan2
- EDAR | c.1037C>A p.T346K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51503718; called by muse, mutect2, varscan2
- EDNRB | c.956C>A p.S319Y (on ENST00000377211 / NM_001201397.1; = p.S229Y on NM_000115.5) | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57523475; called by muse, mutect2, varscan2
- EFCAB6 | c.2745C>G p.N915K | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as rs1368486314, COSV53064948; called by muse, mutect2, varscan2
- EPHA6 | c.2783C>G p.T928S (on ENST00000389672 / NM_001080448.3; = p.T320S on NM_173655.4) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV67575646; called by muse, mutect2, varscan2
- EPHX2 | c.1471G>T p.V491F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1284918396, COSV66845013; called by muse, mutect2, varscan2
- EVI5 | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.63); catalogued as COSV64827616; called by muse, mutect2, varscan2
- F13B | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV66374214; called by muse, mutect2, varscan2
- FAM135B | c.3975G>T p.R1325S | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52730262; called by muse, mutect2, varscan2
- FAR2 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | catalogued as COSV51726305; called by muse, mutect2, varscan2
- FASTKD1 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV70006928; called by muse, mutect2, varscan2
- FEZ1 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs559483840, COSV54029105, COSV54031881; called by muse, varscan2
- FLG | c.7101G>T p.Q2367H | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as COSV100911819; called by muse, mutect2, varscan2
- FLG | c.2653G>T p.G885W | Missense Mutation (SNP) | VAF 175/549 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV64242833; called by muse, mutect2, varscan2
- FOXN4 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54494764; called by muse, mutect2, varscan2
- FPR1 | c.912G>T p.M304I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100494173; called by muse, mutect2, varscan2
- FZD2 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100190641; called by muse, mutect2, varscan2
- GABRB3 | c.1090C>A p.H364N | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54668041; called by muse, mutect2, varscan2
- GALK2 | c.468G>C p.L156F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59102076; called by muse, mutect2, varscan2
- GATC | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.489); catalogued as COSV99985076; called by muse, mutect2, varscan2
- GC | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56737770; called by muse, mutect2, varscan2
- GLG1 | c.2369A>T p.Q790L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV52668389; called by muse, mutect2, varscan2
- GOLIM4 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 47/129 reads (36%) | catalogued as COSV58330091; called by muse, mutect2, varscan2
- GPR142 | c.645C>A p.F215L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59519579; called by muse, mutect2, varscan2
- GPRC5C | c.1400C>G p.A467G (on ENST00000652232; = p.A422G on NM_018653.4) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.423); catalogued as rs759076886, COSV100702944; called by muse, mutect2, varscan2
- GRIN3A | c.2871G>C p.R957S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV62454622; called by muse, mutect2, varscan2
- HBB | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as CD890155, CM014200, COSV58942523; called by muse, mutect2, varscan2
- HCRTR2 | c.335T>A p.L112Q | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63796278; called by muse, mutect2, varscan2
- HCRTR2 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100904250, COSV63796285; called by muse, mutect2, varscan2
- HERC2 | c.5499T>G p.N1833K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV55327654; called by muse, mutect2, varscan2
- HIVEP2 | c.4636G>T p.G1546C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs377180774, COSV50016578; called by muse, mutect2, varscan2
- HNF4A | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV57383910; called by muse, mutect2, varscan2
- HNRNPCL1 | c.630A>C p.K210N | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV58612123, COSV58612215; called by muse, mutect2, varscan2
- HOXB3 | c.846G>C p.M282I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs765777963, COSV57486245, COSV57487098; called by muse, mutect2, varscan2
- HOXC10 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV100329114; called by muse, mutect2, varscan2
- HRH1 | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67955543; called by muse, mutect2, varscan2
- HTR2A | c.549C>A p.H183Q | Missense Mutation (SNP) | VAF 95/220 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101096762; called by muse, mutect2, varscan2
- IGSF10 | c.2059A>C p.I687L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV56786376; called by muse, mutect2, varscan2
- IRGQ | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.02); catalogued as COSV60670827; called by muse, mutect2, varscan2
- IRX5 | c.1150C>G p.R384G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.972); catalogued as COSV58059000, COSV58059032; called by muse, mutect2, varscan2
- ITGA4 | c.1422C>A p.S474R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52000833; called by muse, mutect2, varscan2
- ITIH6 | c.2714C>T p.P905L | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54487913, COSV54489937; called by muse, mutect2, varscan2
- KDM5B | c.1696G>T p.V566L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52508610; called by muse, mutect2
- KRT28 | c.788G>C p.R263P | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368975442, COSV60685319; called by muse, mutect2, varscan2
- KRT31 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99289932; called by muse, mutect2
- KRT6A | c.857C>G p.A286G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV58105587; called by muse, mutect2, varscan2
- KRT86 | c.78C>A p.C26* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV53293024; called by muse, mutect2, varscan2
- LDLRAD3 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV59683345; called by muse, mutect2, varscan2
- LRIF1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100870882; called by muse, mutect2, varscan2
- LRP2 | c.5892G>T p.W1964C | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55557115; called by muse, mutect2, varscan2
- LRRIQ3 | c.116A>T p.H39L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs768274902; called by mutect2, varscan2
- MALT1 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 36/60 reads (60%) | catalogued as COSV61935108; called by muse, mutect2, varscan2
- MBNL2 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.25); catalogued as COSV100600488; called by muse, mutect2, varscan2
- MBTPS2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65268878; called by muse, mutect2, varscan2
- MDC1 | c.2416G>T p.G806W | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV64523834; called by muse, mutect2, varscan2
- METTL24 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV58821145; called by muse, mutect2, varscan2
- MGA | c.3919A>T p.K1307* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV54955744; called by muse, mutect2, varscan2
- MGAM | c.2799C>A p.N933K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV72074821; called by muse, mutect2, varscan2
- MLC1 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61117495; called by muse, mutect2, varscan2
- MORF4L1 | c.923G>A p.R308Q (on ENST00000331268 / NM_206839.2; = p.R269Q on NM_006791.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV58704239, COSV58706058; called by muse, mutect2, varscan2
- MS4A14 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); catalogued as COSV55733231; called by muse, mutect2, varscan2
- MTOR | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 80/132 reads (61%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV63871777; called by muse, mutect2, varscan2
- MUC16 | c.31797G>A p.W10599* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV67471763; called by muse, mutect2, varscan2
- MUC16 | c.24437C>A p.P8146H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV67471772; called by muse, mutect2, varscan2
- MVD | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV56330581; called by muse, mutect2, varscan2
- MYLK4 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs767744025, COSV51142783; called by muse, mutect2, varscan2
- NAA11 | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV54514742; called by muse, mutect2, varscan2
- NAIF1 | c.99C>G p.N33K | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as COSV66091093; called by muse, mutect2, varscan2
- NARS2 | c.727C>G p.R243G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs952741388, COSV55249838; called by muse, mutect2, varscan2
- NAV2 | c.1575G>T p.K525N (on ENST00000396087 / NM_001244963.2; = p.K502N on NM_145117.5) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as COSV62324923; called by muse, mutect2, varscan2
- NAV2 | c.3793C>G p.L1265V (on ENST00000396087 / NM_001244963.2; = p.L1242V on NM_145117.5) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV60660193; called by muse, mutect2, varscan2
- NCKAP5 | c.3293C>G p.T1098R | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.325); catalogued as COSV58448655; called by muse, mutect2, varscan2
- NEXMIF | c.2947G>C p.V983L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50037765; called by muse, mutect2, varscan2
- NLGN4Y | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100196953; called by muse, mutect2, varscan2
- NLRP8 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV52588713; called by muse, mutect2, varscan2
- NPC1L1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs372234110, CM145247; called by muse, mutect2, varscan2
- NPNT | c.368C>G p.P123R | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59754395; called by muse, mutect2, varscan2
- NR4A3 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV58243989; called by muse, mutect2, varscan2
- OLAH | c.211C>A p.L71I (on ENST00000378228 / NM_001039702.3; = p.L124I on NM_018324.3) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV65492709; called by muse, mutect2, varscan2
- OR11A1 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV65821082; called by muse, mutect2, varscan2
- OR2M2 | c.757G>T p.G253* | Nonsense Mutation (SNP) | VAF 46/232 reads (20%) | catalogued as COSV100677269; called by muse, mutect2, varscan2
- OR2M2 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100677270, COSV62898165; called by muse, mutect2, varscan2
- OR2T6 | c.24G>T p.L8F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100861596; called by muse, mutect2
- OR2T6 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63216471; called by muse, mutect2, varscan2
- OR4N2 | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs755552785, COSV60052188; called by muse, mutect2, varscan2
- OR8I2 | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV56168307, COSV56169801; called by muse, mutect2, varscan2
- OR9G4 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs142738268, COSV57248004; called by muse, mutect2, varscan2
- PALB2 | c.1984A>G p.K662E | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as CM151882, COSV55165849; called by muse, mutect2, varscan2
- PCDH10 | c.1924C>G p.R642G | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52095992, COSV52096272; called by muse, mutect2, varscan2
- PCDH10 | c.2911A>G p.S971G | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as rs754484154, COSV99994058; called by muse, mutect2, varscan2
- PCDH19 | c.3071A>T p.D1024V (on ENST00000373034 / NM_001184880.2; = p.D976V on NM_020766.3) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV55264641; called by muse, mutect2, varscan2
- PCDHA1 | c.1752G>T p.L584F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as COSV65373761; called by muse, mutect2, varscan2
- PCDHA1 | c.1753G>C p.V585L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); catalogued as rs782529116, COSV65373181; called by muse, mutect2, varscan2
- PCDHA2 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV100974036; called by muse, mutect2, varscan2
- PCDHA8 | c.1745C>A p.P582Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.293); catalogued as COSV65327429; called by muse, mutect2, varscan2
- PCDHB14 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.677); catalogued as rs142658705; called by muse, mutect2, varscan2
- PCDHB2 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV99165790; called by muse, mutect2, varscan2
- PCDHGA2 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.335); catalogued as COSV53963332; called by muse, mutect2, varscan2
- PDE3B | c.2264G>T p.R755L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56384876; called by muse, mutect2
- PLCB1 | c.3473C>A p.P1158H | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV62054802, COSV62058563; called by muse, mutect2, varscan2
- PLCE1 | c.2212G>T p.E738* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV53353925; called by muse, mutect2, varscan2
- PLEC | c.7052C>T p.A2351V (on ENST00000322810 / NM_201380.4; = p.A2241V on NM_000445.5) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.113); catalogued as rs781956194, COSV59603050, COSV59642717; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); catalogued as COSV57965849; called by muse, mutect2, varscan2
- POLDIP2 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV50228499; called by muse, mutect2, varscan2
- POLR1F | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 138/442 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55998696; called by muse, mutect2, varscan2
- POTEE | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 32/120 reads (27%) | catalogued as rs779229923, COSV100388436, COSV58224609; called by muse, mutect2, varscan2
- PRKCG | c.1610A>G p.D537G | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54728536; called by muse, mutect2
- PRKDC | c.5775G>T p.E1925D | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.841); catalogued as COSV58054579; called by muse, mutect2, varscan2
- PRR30 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53206533; called by muse, mutect2, varscan2
- PRR5 | c.267C>T p.N89= (on ENST00000336985 / NM_181333.4; = p.N80= on NM_015366.4) | Splice Region (SNP) | VAF 4/30 reads (13%) | catalogued as COSV50060937; called by muse, mutect2
- PRRC2B | c.3803G>A p.G1268D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV61938054; called by muse, mutect2, varscan2
- PTPRN | c.2384G>T p.W795L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55348910; called by muse, mutect2, varscan2
- PXDNL | c.2635G>T p.D879Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV62488479; called by muse, mutect2, varscan2
- PZP | c.4348C>G p.P1450A | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54362479; called by muse, mutect2, varscan2
- QSOX1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV62580635; called by muse, mutect2, varscan2
- RABGAP1L | c.1741G>C p.D581H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52300254; called by muse, mutect2, varscan2
- RALGAPB | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53438673; called by muse, mutect2, varscan2
- REG3A | c.5T>C p.L2P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV59409855; called by muse, mutect2, varscan2
- RELN | c.5054A>C p.Q1685P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV59007457; called by muse, mutect2, varscan2
- RGCC | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101037017; called by muse, mutect2, varscan2
- RGS18 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV66508452; called by muse, mutect2, varscan2
- RGS20 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.086); catalogued as COSV52017809; called by muse, mutect2, varscan2
- RLIM | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV60327023; called by muse, mutect2, varscan2
- RNF217 | c.1556G>T p.G519V (on ENST00000521654 / NM_001286398.2; = p.V265= on NM_152553.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs758847605, COSV99255205; called by muse, mutect2, varscan2
- RP1 | c.3185G>A p.R1062K | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55118463; called by muse, mutect2, varscan2
- RP1L1 | c.6720G>T p.E2240D | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV66756118; called by muse, mutect2
- RP1L1 | c.5348C>A p.A1783E | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs374403002, COSV66756122; called by muse, mutect2, varscan2
- RPA4 | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100233991; called by muse, mutect2, varscan2
- RSAD1 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749242780, COSV99364274, COSV99364339; called by mutect2, varscan2
- RUNX1T1 | c.889C>A p.P297T (on ENST00000265814 / NM_001198628.1; = p.P270T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV56149507; called by muse, mutect2, varscan2
- SAAL1 | c.1286A>T p.K429M | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV55516036; called by muse, mutect2, varscan2
- SAP130 | c.421A>C p.M141L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as COSV99385003; called by muse, mutect2
- SBK1 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV104421477, COSV59397271; called by muse, mutect2, varscan2
- SCG2 | c.1751A>G p.Y584C | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV59540462; called by muse, mutect2, varscan2
- SEMG1 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV54873152; called by muse, mutect2, varscan2
- SERPINA3 | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV67586326; called by muse, mutect2, varscan2
- SIRT6 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100511388; called by muse, mutect2, varscan2
- SIX6 | c.475C>A p.R159S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100576521; called by muse, mutect2, varscan2
- SLC20A2 | c.1877G>C p.W626S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60604083; called by muse, mutect2, varscan2
- SLC38A2 | c.1135G>T p.V379L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56745302; called by muse, mutect2, varscan2
- SLC8A1 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as COSV60483042; called by muse, mutect2, varscan2
- SLC9A8 | c.133del p.V45Cfs*16 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | catalogued as COSV64288808; called by mutect2, pindel, varscan2
- SLC9A9 | c.264C>G p.F88L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.067); catalogued as COSV57230334; called by muse, mutect2, varscan2
- SMC3 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as COSV62420510; called by muse, mutect2, varscan2
- SMG8 | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56285684; called by muse, mutect2, varscan2
- SOGA1 | c.2107G>T p.G703C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV52920768; called by muse, mutect2
- SON | c.6359A>T p.D2120V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV51659951; called by muse, mutect2, varscan2
- SOWAHB | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 58/302 reads (19%) | catalogued as COSV57554643; called by muse, mutect2, varscan2
- SPHKAP | c.699T>C p.D233= | Splice Region (SNP) | VAF 9/155 reads (6%) | catalogued as rs1293651252, COSV60867477, COSV60882180; called by muse, mutect2
- SPPL2A | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55941457; called by muse, mutect2, varscan2
- ST18 | c.1398C>T p.H466= | Splice Region (SNP) | VAF 13/81 reads (16%) | catalogued as COSV52496626; called by muse, mutect2, varscan2
- STAB2 | c.3189T>G p.H1063Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66340444; called by muse, mutect2, varscan2
- STXBP2 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200855062, COSV55406039; called by muse, mutect2, varscan2
- SYBU | c.1467G>C p.Q489H (on ENST00000276646 / NM_001099754.2; = p.Q488H on NM_017786.6) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52619117; called by muse, mutect2, varscan2
- TBC1D14 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as COSV101298986, COSV68984477; called by muse, mutect2, varscan2
- TBX15 | c.1778C>A p.S593Y (on ENST00000369429 / NM_001330677.2; = p.S487Y on NM_152380.3) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV52869445; called by muse, mutect2, varscan2
- TCHH | c.3703G>T p.V1235F | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV64275439; called by muse, mutect2, varscan2
- TECRL | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.343); catalogued as COSV67087588; called by muse, mutect2
- TEP1 | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV52987297, COSV52993929; called by muse, mutect2, varscan2
- TESMIN | c.1116C>A p.C372* | Nonsense Mutation (SNP) | VAF 73/235 reads (31%) | catalogued as COSV54833164; called by muse, mutect2, varscan2
- TLN1 | c.6802C>T p.Q2268* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59208234; called by muse, mutect2
- TMCO5A | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60464983; called by muse, mutect2, varscan2
- TMTC1 | c.994G>C p.V332L (on ENST00000539277 / NM_001193451.2; = p.V224L on NM_175861.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV55483774, COSV99760079; called by muse, mutect2, varscan2
- TOX2 | c.1156C>A p.Q386K (on ENST00000358131 / NM_001098798.2; = p.Q362K on NM_032883.3) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV57887636; called by muse, mutect2, varscan2
- TPH2 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 109/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61592388; called by muse, mutect2, varscan2
- TRAF2 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV56038402; called by muse, mutect2, varscan2
- TRAPPC8 | c.2090G>A p.S697N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs1242231680, COSV51972178; called by muse, mutect2
- TRIM42 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as COSV53883654; called by muse, mutect2, varscan2
- TRIM42 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV53880822, COSV53883667; called by muse, mutect2, varscan2
- TRMT6 | c.1206G>T p.Q402H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV52544003; called by muse, mutect2, varscan2
- TSHZ1 | c.1638G>C p.K546N (on ENST00000580243 / NM_001308210.2; = p.K501N on NM_005786.6) | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV59010928, COSV59015813; called by muse, mutect2, varscan2
- TSPAN31 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs776811811, COSV57276384; called by muse, mutect2, varscan2
- TTN | c.72038A>G p.N24013S (on ENST00000591111; = p.N16589S on NM_003319.4) | Missense Mutation (SNP) | VAF 58/239 reads (24%) | PolyPhen benign (0.02); catalogued as COSV60112273; called by muse, mutect2, varscan2
- TYR | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV54477352; called by muse, mutect2, varscan2
- UNC79 | c.3997C>G p.R1333G (on ENST00000393151 / NM_001346218.2; = p.R1156G on NM_020818.5) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV56374097, COSV56391617; called by muse, mutect2, varscan2
- UPP2 | c.704G>T p.R235I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV50047398; called by muse, mutect2, varscan2
- USP36 | c.3364C>T p.R1122C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs760609215, COSV61752001; called by muse, mutect2, varscan2
- UTRN | c.5797G>T p.D1933Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62337479; called by muse, mutect2, varscan2
- VCAN | c.936G>C p.R312S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54098515, COSV54107023; called by muse, mutect2
- VCAN | c.9760C>A p.Q3254K | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54107035; called by muse, mutect2, varscan2
- VWF | c.3611G>T p.R1204L | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV104373060, COSV54622953; called by muse, mutect2, varscan2
- WDHD1 | c.3102G>T p.L1034F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV62214235; called by muse, mutect2, varscan2
- WDR64 | c.1384C>G p.L462V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV63796697; called by muse, mutect2, varscan2
- WNT8A | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100843069; called by muse, mutect2, varscan2
- XIRP1 | c.3947C>T p.P1316L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV61138972; called by muse, mutect2, varscan2
- XIRP2 | c.1198C>A p.Q400K (on ENST00000628543; = p.Q575K on NM_152381.6) | Missense Mutation (SNP) | VAF 121/163 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV54706291; called by muse, mutect2, varscan2
- ZC3H4 | c.1331-1C>T p.X444_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV53413541; called by muse, mutect2
- ZEB1 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58045955; called by muse, mutect2, varscan2
- ZFYVE26 | c.4882C>T p.H1628Y | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61329440; called by muse, mutect2, varscan2
- ZNF135 | c.527C>A p.P176Q (on ENST00000313434 / NM_001289401.2; = p.P188Q on NM_003436.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV57882860; called by muse, mutect2, varscan2
- ZNF385B | c.99C>G p.D33E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.007); catalogued as COSV69803433; called by muse, mutect2, varscan2
- ZNF408 | c.1988G>T p.R663I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV100305562; called by muse, mutect2, varscan2
- ZNF43 | c.1983G>T p.W661C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV61683187; called by muse, mutect2, varscan2
- ZNF480 | c.302G>T p.R101M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.62); catalogued as COSV57996575; called by muse, mutect2
- ZNF484 | c.1328G>T p.S443I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as COSV60258040; called by muse, mutect2, varscan2
- ZNF536 | c.2959C>T p.L987F | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1248853592, COSV62825816; called by muse, mutect2, varscan2
- ZNF813 | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV67176773; called by muse, mutect2, varscan2
- ZSCAN4 | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV56591872, COSV56593345; called by muse, mutect2, varscan2
- ARHGEF5 | c.1232T>A p.I411K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by mutect2, varscan2
- CYB5R4 | c.214dup p.W72Lfs*10 | Frame Shift Ins (INS) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- DCBLD2 | c.1516del p.E506Nfs*14 | Frame Shift Del (DEL) | VAF 54/158 reads (34%) | called by mutect2, pindel, varscan2
- GPC6 | c.1577_1578del p.E526Gfs*42 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by pindel, varscan2
- HAUS6 | c.2210A>G p.D737G | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRIQ3 | c.114dup p.H39Sfs*15 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- NLRP8 | c.285_287del p.R96del | In Frame Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- PRAMEF10 | c.531del p.V178Cfs*51 | Frame Shift Del (DEL) | VAF 26/109 reads (24%) | called by mutect2, pindel, varscan2
- ROBO3 | c.1000del p.R334Afs*17 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- SDK2 | c.5864dup p.Q1956Pfs*30 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3947C>T p.S1316F | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SRGAP3 | c.635del p.R212Pfs*4 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- SYNRG | c.1232G>C p.G411A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TACR3 | c.741_742del p.Y247* | Nonsense Mutation (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel*, varscan2*
- TDRD9 | c.2981del p.L994* | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, varscan2
- UBE2NL | c.313G>C p.V105L | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZZEF1 | c.6376del p.A2126Qfs*4 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- ABCB11 | c.2781T>A p.S927= | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as COSV55592988; called by muse, mutect2, varscan2
- ABCC12 | c.3486G>A p.S1162= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs368132634; called by muse, mutect2, varscan2
- ADD2 | c.1575C>T p.A525= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs201133279, COSV52462607; called by muse, mutect2, varscan2
- ARHGAP6 | c.1353G>C p.G451= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV57290959, COSV57297076; called by muse, mutect2, varscan2
- ARHGEF7 | c.1455G>A p.Q485= (on ENST00000375741 / NM_001113511.2; = p.Q307= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV54544708, COSV54546973; called by muse, mutect2, varscan2
- ATP7A | c.3042G>T p.V1014= | Silent (SNP) | VAF 61/99 reads (62%) | catalogued as COSV58447482; called by muse, mutect2, varscan2
- BARX2 | c.81C>T p.I27= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as COSV55650750; called by muse, mutect2, varscan2
- BBS10 | c.1536A>G p.T512= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as COSV67913238; called by muse, mutect2, varscan2
- BPIFA1 | c.147A>G p.G49= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV62824582; called by muse, mutect2, varscan2
- BTN1A1 | c.870G>C p.L290= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV55068046; called by muse, mutect2, varscan2
- CCDC88A | c.780A>T p.I260= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV55063164; called by muse, mutect2, varscan2
- CDH7 | c.1704A>T p.G568= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV59887548, COSV59895574; called by muse, mutect2, varscan2
- CHST8 | c.25C>A p.R9= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV52859585, COSV52865074; called by muse, mutect2, varscan2
- CYP39A1 | c.1128A>G p.P376= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV51496330; called by muse, mutect2, varscan2
- CYTH3 | c.486G>A p.A162= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs760794383, COSV100641419; called by muse, mutect2, varscan2
- DNAH9 | c.11460T>C p.S3820= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV52353724; called by muse, mutect2, varscan2
- DST | c.3426A>G p.S1142= (on ENST00000361203 / NM_001374722.1; = p.S816= on NM_001723.6) | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV55019191; called by muse, mutect2, varscan2
- FAM135B | c.3465C>A p.L1155= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV52730280, COSV99424086; called by muse, mutect2, varscan2
- FAM47B | c.570G>T p.R190= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1265915647, COSV61452600, COSV61454419; called by muse, mutect2, varscan2
- GATC | c.204C>T p.R68= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99985078; called by muse, mutect2, varscan2
- GCK | c.144G>A p.E48= | Silent (SNP) | VAF 45/195 reads (23%) | catalogued as COSV61754215; called by muse, mutect2, varscan2
- GDA | c.1086C>T p.S362= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV52993973; called by muse, mutect2, varscan2
- GPR101 | c.135T>G p.S45= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99981526; called by muse, mutect2, varscan2
- ITGA6 | c.2883A>G p.K961= (on ENST00000442250; = p.K922= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/205 reads (20%) | catalogued as COSV51228272; called by muse, mutect2, varscan2
- ITSN1 | c.2448G>T p.V816= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV66083731; called by muse, mutect2, varscan2
- JAKMIP2 | c.909C>A p.T303= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV54606353; called by muse, mutect2, varscan2
- KIF21B | c.375C>A p.A125= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100145043, COSV59759265; called by muse, mutect2, varscan2
- KIR3DL1 | c.1173A>G p.Q391= | Silent (SNP) | VAF 35/236 reads (15%) | catalogued as COSV58491839; called by muse, mutect2, varscan2
- KLK3 | c.462C>A p.A154= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV58098959, COSV58100915; called by muse, mutect2, varscan2
- LAMB4 | c.4638A>G p.A1546= | Silent (SNP) | VAF 75/178 reads (42%) | catalogued as COSV52721110; called by muse, mutect2, varscan2
- LIG3 | c.1341G>A p.L447= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99252897; called by muse, mutect2, varscan2
- LIG4 | c.2061T>G p.G687= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV63597204; called by muse, mutect2, varscan2
- LRIF1 | c.111G>T p.S37= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100870843, COSV100870883; called by muse, mutect2, varscan2
- LRRC4C | c.822G>T p.L274= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV53427704; called by muse, mutect2, varscan2
- LTBP4 | c.726C>T p.G242= (on ENST00000308370 / NM_001042544.1; = p.G205= on NM_003573.2) | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52583147; called by muse, mutect2, varscan2
- MOS | c.63G>A p.A21= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs374238566; called by muse, mutect2, varscan2
- MRPS36 | c.54A>G p.P18= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99841076; called by muse, mutect2, varscan2
- MUC7 | c.411C>A p.T137= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV59218496; called by muse, mutect2, varscan2
- MXRA5 | c.5355G>T p.P1785= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV99478086; called by muse, mutect2, varscan2
- NAMPT | c.465C>T p.S155= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV55995338, COSV99748189; called by muse, mutect2, varscan2
- NRG1 | c.1584C>A p.T528= (on ENST00000405005 / NM_013964.5; = p.T533= on NM_013956.5) | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99828798; called by muse, mutect2
- OBSCN | c.12255C>G p.A4085= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV52782788, COSV52792388; called by muse, mutect2, varscan2
- OR10G7 | c.255C>G p.S85= | Silent (SNP) | VAF 44/205 reads (21%) | catalogued as COSV100389687, COSV57867441; called by muse, mutect2, varscan2
- PCDH10 | c.2910C>A p.R970= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV99994051; called by muse, mutect2, varscan2
- PCDH7 | c.2481T>A p.T827= | Silent (SNP) | VAF 55/150 reads (37%) | called by muse, mutect2, varscan2
- PCDHA2 | c.102C>G p.S34= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs782150347, COSV100974038, COSV65364715; called by muse, mutect2, varscan2
- PCDHB2 | c.1743G>T p.A581= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99165054, COSV99165789; called by muse, mutect2, varscan2
- PCDHGA3 | c.1854G>T p.S618= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV53939566, COSV99542335; called by muse, mutect2, varscan2
- PHYH | c.735G>T p.R245= | Silent (SNP) | VAF 52/217 reads (24%) | catalogued as COSV53816274; called by muse, mutect2, varscan2
- POTEE | c.2649G>T p.R883= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs1231698006, COSV100388435; called by muse, mutect2, varscan2
- PREX1 | c.1770C>T p.S590= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV64252705; called by muse, mutect2, varscan2
- PROM2 | c.1962G>T p.L654= | Silent (SNP) | VAF 77/117 reads (66%) | catalogued as COSV58298558; called by muse, mutect2, varscan2
- PSMC4 | c.66G>T p.R22= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as COSV50095777; called by muse, mutect2, varscan2
- RNF168 | c.594C>T p.P198= | Silent (SNP) | VAF 51/139 reads (37%) | catalogued as COSV58838168; called by muse, mutect2, varscan2
- RNF213 | c.10626C>T p.S3542= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs756612314, COSV60399599; called by muse, mutect2, varscan2
- RPGRIP1 | c.789T>A p.A263= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV52851094; called by muse, mutect2, varscan2
- RPGRIP1 | c.2109A>T p.I703= | Silent (SNP) | VAF 50/120 reads (42%) | catalogued as COSV99250297, COSV99251397; called by muse, mutect2, varscan2
- RRP12 | c.3099C>G p.V1033= | Silent (SNP) | VAF 10/151 reads (7%) | catalogued as COSV59668355; called by muse, mutect2
- SALL1 | c.1587C>A p.G529= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV51758767; called by muse, mutect2, varscan2
- SIPA1L2 | c.2772G>T p.S924= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs187053345, COSV53391884; called by muse, mutect2, varscan2
- SLC5A8 | c.99C>A p.A33= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV73310744; called by muse, mutect2, varscan2
- ST8SIA1 | c.45C>A p.A15= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV53954830; called by muse, mutect2, varscan2
- STAT1 | c.981G>T p.T327= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV61189957; called by muse, mutect2, varscan2
- STAT3 | c.1995C>T p.I665= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV52888488; called by muse, mutect2, varscan2
- TENM2 | c.7692C>A p.T2564= (on ENST00000518659 / NM_001122679.2; = p.T2325= on NM_001080428.3) | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV69132314; called by muse, mutect2, varscan2
- TMEM200A | c.1020C>T p.P340= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs544062748, COSV51653988; called by muse, mutect2, varscan2
- TMEM225 | c.225C>A p.G75= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV66693451; called by muse, mutect2, varscan2
- TMPRSS11B | c.582G>T p.G194= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs757210999, COSV100219449; called by muse, mutect2, varscan2
- TRAPPC8 | c.2088A>T p.V696= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV51972189; called by muse, mutect2
- UBE2NL | c.312A>T p.T104= | Silent (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- UPRT | c.624G>T p.L208= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as COSV64920276; called by muse, mutect2, varscan2
- VEGFC | c.1044C>T p.P348= | Silent (SNP) | VAF 83/189 reads (44%) | catalogued as COSV54599309; called by muse, mutect2, varscan2
- VGF | c.1617G>A p.P539= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV50801966; called by muse, mutect2, varscan2
- ZDBF2 | c.5040G>T p.L1680= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV65626810; called by muse, mutect2, varscan2
- ZFR | c.720G>T p.A240= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1163978499, COSV54053868; called by muse, mutect2, varscan2
- ZMYND10 | c.1041C>A p.G347= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- ZNF592 | c.2217G>A p.G739= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs767729667, COSV55437423; called by muse, mutect2, varscan2
- ZNF780B | c.1185G>C p.G395= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV55465001; called by muse, mutect2, varscan2
- ZNF786 | c.1932C>T p.S644= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs573027357, COSV60276436; called by muse, mutect2, varscan2
- AC004080.3 | c.11-4554C>A | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as rs746028052, COSV52229090; called by muse, mutect2, varscan2
- ANXA13 | c.15+1548C>A | Intron (SNP) | VAF 18/144 reads (13%) | catalogued as COSV99146035; called by muse, mutect2, varscan2
- DCHS2 | n.85G>C | RNA (SNP) | VAF 12/25 reads (48%) | catalogued as COSV59728593; called by muse, mutect2, varscan2
- DST | c.4297-4558G>T | Intron (SNP) | VAF 64/182 reads (35%) | catalogued as COSV99758189; called by muse, mutect2, varscan2
- DST | c.4296+4195G>T | Intron (SNP) | VAF 31/105 reads (30%) | catalogued as COSV99758191; called by muse, mutect2, varscan2
- WNT8A | c.*303G>T | 3'UTR (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100843063; called by muse, mutect2, varscan2
